Somatic mutation profile of tumor specimen TCGA-X7-A8M8-01A (aliquot TCGA-X7-A8M8-01A-11D-A423-09) from TCGA case TCGA-X7-A8M8, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B2, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 45.8 years (16,741 days).
Specimen TCGA-X7-A8M8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2a683d7-7479-44e5-b355-a74d5336a6a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X7-A8M8-10A (Blood Derived Normal), aliquot TCGA-X7-A8M8-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca223a9a-5bcb-40f3-8c45-51afd24641a2

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 18/452 reads (4%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- CNTN2 | c.278del p.G93Afs*6 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by pindel, varscan2
- DCAF6 | c.1047A>T p.L349F | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CT47A6 | c.645C>T p.A215= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as rs753132845; called by muse, mutect2
- EFHC2 | c.1326C>T p.V442= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
